Gene-level copy-number profile of tumor specimen TCGA-DK-A1A6-01A from TCGA case TCGA-DK-A1A6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.5 years (19,554 days).
Specimen TCGA-DK-A1A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0b13a410-4c36-44a2-9110-d6a649494678.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1A6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a9af501-7ab7-4fa4-b3bf-714e031ca191

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 96; copy number 2: 10,212; copy number 3: 27,899; copy number 4: 13,620; copy number 5: 2,612; copy number 6: 2,561; copy number 7: 1,358; copy number 8: 653; copy number 9: 249; copy number 10: 86; copy number 11: 106; copy number 12: 54; copy number 13: 17; copy number 14: 10; copy number 15: 29; copy number 16: 29; copy number 18: 104; copy number 22: 34; copy number 30: 40; copy number 33: 14; copy number 40: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,792 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,395,943–72,282,539, 1 gene, copy number 9 (within-gene range 2–9): NEGR1.
- chr1:71,738,173–81,252,096, 120 genes, copy number 8–9 (broad region; genes not listed).
- chr1:81,426,456–81,625,713, 7 genes, copy number 8: HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2.
- chr2:97,618,638–102,736,888, 94 genes, copy number 8–11 (broad region; genes not listed).
- chr2:157,033,837–164,352,223, 100 genes, copy number 7–10 (broad region; genes not listed).
- chr3:96,349,554–165,846,519, 1,153 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:13,547,704–13,826,574, 8 genes, copy number 8: RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1.
- chr6:16,232,231–23,857,646, 86 genes, copy number 8–12 (broad region; genes not listed).
- chr6:26,956,932–27,912,396, 58 genes, copy number 8 (within-gene range 6–8): LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.5, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, AL009179.2, LINC01012, GPR89P, AL009179.1, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12, H2BC15, H2AC15, H2BC16P, H2AC16, H1-5, H3C11, H4C13, H3C12, H2AC17, H2BC17, RNU7-26P, OR2B2.
- chr8:38,382,364–47,736,306, 162 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:76,406,654–90,095,475, 188 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:92,668,660–95,156,685, 68 genes, copy number 8–13 (broad region; genes not listed).
- chr8:95,206,876–95,403,894, 3 genes, copy number 9: LINC01298, C8orf37, AC024995.1.
- chr8:95,947,781–102,688,906, 148 genes, copy number 8–18 (broad region; genes not listed).
- chr8:106,215,763–106,272,902, 3 genes, copy number 7: SLC16A14P1, AC027031.1, AC027031.2.
- chr8:113,438,334–126,329,538, 162 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr10:16,005,808–16,295,858, 4 genes, copy number 9: AL358033.1, FTLP19, RNU6-1075P, LINC02654.
- chr10:37,776,526–37,858,106, 1 gene, copy number 7 (within-gene range 4–7): ZNF248.
- chr10:37,818,606–38,762,491, 32 genes, copy number 7: TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1.
- chr10:61,901,684–62,304,033, 3 genes, copy number 7 (within-gene range 4–7): ARID5B, RTKN2, LINC02621.
- chr11:67,812,557–70,189,528, 69 genes, copy number 12–40 (within-gene range 4–40) (broad region; genes not listed).
- chr11:73,787,872–74,311,640, 20 genes, copy number 8 (within-gene range 4–8): MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1.
- chr12:81,998,632–83,172,740, 12 genes, copy number 8: AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr17:39,210,541–39,864,312, 22 genes, copy number 7–14: STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr19:56,922,018–58,605,223, 134 genes, copy number 8–15 (broad region; genes not listed).
- chr21:10,328,411–19,345,312, 134 genes, copy number 9–33 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
